Gene-level copy-number profile of tumor specimen TCGA-B5-A0K3-01A from TCGA case TCGA-B5-A0K3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 62.1 years (22,664 days).
Specimen TCGA-B5-A0K3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.5dcc7526-fd50-480d-b9ed-0a4bb2323d6a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B5-A0K3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3bf1c00c-62a9-4a19-890e-dd36eafc1eae

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,191; copy number 2: 43,811; copy number 3: 2,777; copy number 4: 1,634; copy number 5: 300; copy number 6: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B5-A0K3-01A-11D-A042-01): tumor purity 0.76, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 388 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:112,736,349–114,007,304, 52 genes, copy number 5 (within-gene range 3–5): CKAP2L, IL1A, AC079753.2, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3.
- chr3:141,228,726–141,367,753, 1 gene, copy number 5 (within-gene range 2–5): PXYLP1.
- chr3:141,267,353–142,225,592, 24 genes, copy number 5 (within-gene range 2–5): AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5.
- chr3:169,613,510–169,812,986, 12 genes, copy number 6 (within-gene range 4–6): AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2.
- chr3:193,593,144–194,003,760, 9 genes, copy number 5 (within-gene range 4–5): OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026.
- chr6:7,107,597–7,541,338, 16 genes, copy number 5 (within-gene range 3–5): RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1.
- chr6:11,183,298–11,516,466, 6 genes, copy number 6 (within-gene range 2–6): NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5.
- chr6:37,630,679–38,154,624, 6 genes, copy number 5 (within-gene range 2–5): MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:43,474,186–43,852,333, 22 genes, copy number 6: RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr6:111,299,028–111,483,715, 1 gene, copy number 5 (within-gene range 2–5): REV3L.
- chr6:111,430,260–111,606,906, 6 genes, copy number 5: BRD7P4, TRAF3IP2-AS1, AL136310.1, AL008730.1, TRAF3IP2, Z97989.1.
- chr6:158,109,519–158,199,344, 2 genes, copy number 5: SERAC1, GTF2H5.
- chr6:158,237,336–158,242,797, 1 gene, copy number 5: SRP72P2.
- chr6:158,296,671–158,303,372, 1 gene, copy number 5: AL360169.3.
- chr7:74,289,407–74,405,935, 1 gene, copy number 5: CLIP2.
- chr8:141,055,290–141,518,737, 20 genes, copy number 5: AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1.
- chr9:35,490,111–35,561,898, 1 gene, copy number 5 (within-gene range 2–5): RUSC2.
- chr9:35,561,831–35,870,601, 33 genes, copy number 5: FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1.
- chr9:136,440,096–136,793,317, 27 genes, copy number 6: SEC16A, C9orf163, NOTCH1, MIR4673, AL592301.1, MIR4674, NALT1, LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141.
- chr14:76,761,468–77,117,287, 21 genes, copy number 6 (within-gene range 3–6): VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4, LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC.
- chr17:47,733,236–48,067,293, 24 genes, copy number 5 (within-gene range 1–5): TBX21, OSBPL7, MRPL10, LRRC46, SCRN2, SP6, AC018521.3, AC018521.7, AC018521.5, SP2, SP2-AS1, AC018521.6, PNPO, AC018521.1, AC018521.2, PRR15L, CDK5RAP3, AC018521.4, COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2.
- chr18:2,688,564–3,025,566, 11 genes, copy number 5 (within-gene range 2–5): AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70.
- chr19:13,731,760–14,007,039, 19 genes, copy number 5 (within-gene range 3–5): CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1.
- chr19:50,830,530–51,390,591, 53 genes, copy number 5: AC011523.1, KLK3, KLK2, KLKP1, KLK4, PPIAP59, KLK5, AC011483.2, KLK6, AC011483.3, AC011483.1, KLK7, KLK8, AC011473.4, KLK9, KLK10, AC011473.2, KLK11, KLK12, AC011473.3, AC011473.1, KLK13, KLK14, CTU1, SIGLEC18P, SIGLEC9, AC063977.2, SIGLEC7, AC063977.1, AC063977.5, AC063977.6, SIGLEC17P, SIGLEC20P, AC063977.4, SIGLEC21P, MIR8074, SIGLEC22P, CD33, SIGLECL1, AC063977.3, LINC01872, SIGLEC24P, IGLON5, VSIG10L, AC008750.2, AC008750.3, ETFB, AC008750.7, AC008750.4, CLDND2, NKG7, LIM2, C19orf84.
- chr20:32,109,714–32,439,319, 11 genes, copy number 5: TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.
- chr20:32,449,755–32,487,019, 2 genes, copy number 5: AL034550.1, AL034550.3.
- chr20:36,651,766–36,746,090, 1 gene, copy number 5 (within-gene range 2–5): NDRG3.
- chr20:36,751,791–36,951,843, 5 genes, copy number 5: DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1.

Autosomal genes at a single copy (total copy number 1): 11,191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
